Gene-level copy-number profile of tumor specimen TCGA-G3-A6UC-01A from TCGA case TCGA-G3-A6UC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 65.1 years (23,793 days).
Specimen TCGA-G3-A6UC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.415da039-7a44-4d01-8a2d-eba57e7f3620.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G3-A6UC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d139549e-15d5-46e9-a7e1-1aefcdd485d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 4,430; copy number 2: 45,453; copy number 3: 7,641; copy number 4: 579; copy number 5: 1,503; copy number 6: 116; copy number 7: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G3-A6UC-01A-21D-A33B-01): tumor purity 0.93, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:4,787,332–5,476,966, 8 genes: PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,702 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,418,210–158,494,886, 7 genes, copy number 5: OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P.
- chr2:195,003,711–195,026,370, 1 gene, copy number 5: AC010983.1.
- chr4:59,833,175–59,834,167, 2 genes, copy number 6: Y_RNA, RNU6-1325P.
- chr5:125,966,777–125,968,085, 1 gene, copy number 5: RPSAP37.
- chr5:155,491,336–155,493,598, 1 gene, copy number 5: AC008725.1.
- chr6:167,607–58,438,364, 1,527 genes, copy number 5–7 (broad region; genes not listed).
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr8:132,775,358–132,848,807, 3 genes, copy number 6 (within-gene range 2–6): PHF20L1, AF230666.2, AF230666.1.
- chr9:14,475–11,618,621, 158 genes, copy number 5 (broad region; genes not listed).
- chr11:112,977,353–112,977,420, 1 gene, copy number 5: RNU7-187P.

Autosomal genes at a single copy (total copy number 1): 2,815. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
